Gene-level copy-number profile of specimen HCM-SANG-0519-C20-85A-01D-A80T-32 from HCMI case HCM-SANG-0519-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectum, NOS; Tumor grade: G3.
Specimen HCM-SANG-0519-C20-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 41132d2d-52fd-4873-9042-2c319ca51bdf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0519-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/5d93ce61-2ef0-4947-bfe0-383e2bddf757

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 14,661; copy number 2: 40,568; copy number 3: 3,526; copy number 4: 162.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 11,806. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
